Somatic mutation profile of tumor specimen TCGA-QC-A7B5-01A (aliquot TCGA-QC-A7B5-01A-11D-A33E-09) from TCGA case TCGA-QC-A7B5, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 75.4 years (27,556 days).
Specimen TCGA-QC-A7B5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1fdaf2a-4cba-403f-bdf5-6b7117cea035.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QC-A7B5-11A (Solid Tissue Normal), aliquot TCGA-QC-A7B5-11A-11D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d66a02d0-5e7d-4a98-999c-4285514543ad

The open-access MAF lists 2,459 somatic variants for this specimen: 1,594 protein-altering or splice-affecting, 807 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,448, Silent 807, Nonsense Mutation 88, Splice Region 22, Splice Site 21, Intron 20, RNA 15, Frame Shift Del 9, 3'UTR 8, 5'Flank 8, 5'UTR 6, In Frame Del 3.

Variants (750 of 2,459; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TAF1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 61/87 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs767354861, COSV52126957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11192G>A p.G3731E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101446933; called by muse, mutect2, varscan2
- ABCA3 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100068404; called by muse, mutect2
- ABCC3 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV99559086; called by muse, mutect2, varscan2
- ABCC8 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs780077643, COSV56853758; called by muse, mutect2, varscan2
- ABHD17A | c.608A>T p.Y203F (on ENST00000292577 / NM_001130111.2; = p.Y254F on NM_031213.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV99171271; called by muse, mutect2, varscan2
- ABHD17A | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99171274; called by muse, mutect2, varscan2
- ABI3BP | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV52543827; called by muse, mutect2, varscan2
- ABI3BP | c.2507A>G p.N836S | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426557; called by muse, mutect2, varscan2
- AC008397.2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); catalogued as COSV99441633; called by muse, varscan2
- AC139530.2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.006); catalogued as COSV100230470; called by muse, mutect2, varscan2
- AC139530.2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100230471; called by muse, mutect2, varscan2
- ACAD11 | c.638A>G p.D213G | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99391959; called by muse, mutect2, varscan2
- ACAD9 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV100459181; called by muse, mutect2, varscan2
- ACBD6 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100852473; called by muse, mutect2, varscan2
- ACCSL | c.948G>A p.E316= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as COSV101122182, COSV99074396; called by mutect2, varscan2
- ACE | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as COSV99326942; called by muse, mutect2
- ACIN1 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52975631; called by muse, mutect2, varscan2
- ACSL6 | c.1204C>T p.R402W (on ENST00000379240; = p.R427W on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs767616461, COSV57303303; called by muse, mutect2, varscan2
- ACSM4 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV101257125, COSV68066847; called by muse, mutect2, varscan2
- ACSM4 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV101257126, COSV101257422; called by muse, mutect2, varscan2
- ACTBL2 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs775736072, COSV101379317; called by muse, mutect2, varscan2
- ACTN4 | c.1727C>T p.T576I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV99400139; called by muse, mutect2, varscan2
- ADAD1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV99635563; called by muse, mutect2, varscan2
- ADAM2 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs759462015, COSV99697273; called by muse, mutect2, varscan2
- ADAM9 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101166088; called by muse, mutect2, varscan2
- ADAMTS12 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100710838; called by muse, mutect2, varscan2
- ADAMTS20 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101239234; called by muse, mutect2, varscan2
- ADAMTS3 | c.2288A>G p.Y763C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1399517876, COSV99710973; called by muse, mutect2, varscan2
- ADCY3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); catalogued as COSV99568182; called by muse, mutect2, varscan2
- ADGRA2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100177884; called by muse, mutect2
- ADGRA3 | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99293217; called by muse, mutect2, varscan2
- ADGRB3 | c.2729G>A p.R910K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53245375; called by muse, mutect2, varscan2
- ADGRG3 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs766481649, COSV100342356; called by muse, mutect2, varscan2
- ADGRG7 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs373804273, COSV56297862; called by muse, mutect2, varscan2
- ADGRV1 | c.4974T>G p.N1658K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.95); catalogued as COSV101315837; called by muse, mutect2, varscan2
- ADGRV1 | c.8249A>T p.N2750I | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV101315838; called by muse, mutect2, varscan2
- ADIPOR1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV100579505; called by muse, mutect2, varscan2
- ADNP | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs772698299, COSV100823728; called by muse, mutect2, varscan2
- ADNP2 | c.3229T>A p.S1077T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100080796; called by muse, mutect2
- ADORA3 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as rs1483083476, COSV99598714; called by muse, mutect2, varscan2
- ADRA2C | c.1367G>A p.R456K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100342602; called by muse, mutect2, varscan2
- AGAP2 | c.1475G>A p.R492H (on ENST00000547588 / NM_001122772.2; = p.R156H on NM_014770.4) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs763488738, COSV99223030; called by muse, mutect2, varscan2
- AGER | c.692-1G>A p.X231_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100426178; called by muse, mutect2, varscan2
- AGT | c.1271T>G p.V424G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794338, COSV64184234; called by muse, mutect2, varscan2
- AHCTF1 | c.4705G>A p.G1569R (on ENST00000366508; = p.G1543R on NM_015446.5) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV100403587; called by muse, mutect2, varscan2
- AHDC1 | c.4777C>T p.H1593Y | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV99899249; called by muse, mutect2, varscan2
- AHNAK | c.14258C>T p.P4753L | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773538633, COSV99947203; called by muse, mutect2, varscan2
- AHNAK | c.14257C>T p.P4753S | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99947206; called by muse, mutect2, varscan2
- AHNAK2 | c.12464C>T p.S4155F | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100317357; called by muse, mutect2, varscan2
- AHSA1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV99375948; called by muse, mutect2, varscan2
- AK5 | c.1409G>A p.G470E (on ENST00000354567 / NM_174858.3; = p.G444E on NM_012093.4) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100642644; called by muse, mutect2, varscan2
- AK9 | c.5060A>C p.N1687T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV101413966, COSV69852781; called by muse, mutect2
- AKAP8L | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 48/111 reads (43%) | catalogued as rs532848259, COSV101275792; called by muse, mutect2, varscan2
- AKR1C4 | c.182T>C p.V61A | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99578664; called by muse, mutect2, varscan2
- AL035460.1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100730132; called by muse, mutect2
- ALDH1L2 | c.2245-1G>A p.X749_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99310986; called by muse, mutect2, varscan2
- ALDH2 | c.1532A>C p.K511T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV99922920; called by muse, mutect2, varscan2
- ALDOB | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100878857; called by muse, mutect2, varscan2
- ALG13 | c.3173C>T p.S1058L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99322124; called by muse, mutect2, varscan2
- ALG9 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 21/50 reads (42%) | catalogued as COSV101211885; called by muse, mutect2, varscan2
- ALKBH6 | c.187G>A p.G63R (on ENST00000252984 / NM_001297701.2; = p.G91R on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV99431019; called by muse, mutect2, varscan2
- ALOXE3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV58554928; called by muse, mutect2, varscan2
- ALPI | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.112); catalogued as COSV99785896; called by muse, mutect2, varscan2
- AMPD1 | c.1512C>G p.F504L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100815017, COSV62416539, COSV62418637; called by muse, mutect2, varscan2
- ANGPTL2 | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.206); catalogued as COSV99401550; called by muse, mutect2, varscan2
- ANGPTL2 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as COSV99401556; called by muse, varscan2
- ANK1 | c.5120G>A p.G1707D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as COSV99225033; called by muse, mutect2, varscan2
- ANK1 | c.5035G>A p.G1679R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99225035; called by muse, mutect2, varscan2
- ANK1 | c.3245C>T p.S1082F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99225055; called by muse, mutect2, varscan2
- ANK2 | c.3896T>C p.F1299S | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100001420; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4873T>A p.Y1625N | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.014); catalogued as rs200665904, COSV99783170; called by muse, mutect2, varscan2
- ANKLE2 | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1487489591, COSV100514087; called by muse, mutect2, varscan2
- ANKRD17 | c.6929C>T p.P2310L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV100429131; called by muse, mutect2, varscan2
- ANKRD23 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as rs746600607, COSV100450410; called by muse, mutect2, varscan2
- ANKRD30A | c.1855C>T p.P619S (on ENST00000611781; = p.P563S on NM_052997.2) | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.901); catalogued as rs1463120955, COSV100653439, COSV64623993; called by muse, mutect2, varscan2
- ANKRD34B | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100103513; called by muse, varscan2
- ANKRD35 | c.1517A>C p.K506T | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841715; called by muse, mutect2, varscan2
- ANKRD42 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99473768; called by muse, mutect2, varscan2
- ANO2 | c.2414G>A p.G805E (on ENST00000356134 / NM_001278597.3; = p.G809E on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100500772; called by muse, mutect2, varscan2
- ANO7 | c.1010G>A p.R337K (on ENST00000274979; = p.R283K on NM_001370694.2) | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.253); catalogued as COSV99238234; called by muse, mutect2, varscan2
- AOC1 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs774495004, COSV62870526; called by muse, mutect2
- AOX1 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV65982819; called by muse, mutect2, varscan2
- AP002512.3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1360393540, COSV54406256; called by muse, mutect2, varscan2
- APBA1 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99595990; called by muse, mutect2, varscan2
- APBA2 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV101258154; called by muse, mutect2, varscan2
- APC | c.7678C>T p.R2560* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV57378917; called by muse, mutect2, varscan2
- APLNR | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99951416; called by muse, mutect2, varscan2
- APOB | c.4525C>T p.P1509S | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV51945572; called by muse, mutect2, varscan2
- APOF | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs778120152, COSV58477230; called by muse, mutect2, varscan2
- APOF | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100028852; called by muse, mutect2, varscan2
- APOL4 | c.223G>A p.E75K (on ENST00000352371 / NM_145660.2; = p.E72K on NM_030643.4) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100274109; called by muse, mutect2, varscan2
- APOL5 | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99968380; called by muse, mutect2
- AQP5 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs139623970, COSV99527459; called by muse, mutect2, varscan2
- AQP5 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754419280, COSV99527462; called by muse, mutect2, varscan2
- ARAP2 | c.3412T>A p.F1138I | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100394576; called by muse, mutect2, varscan2
- ARFGEF2 | c.3544G>T p.D1182Y | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100904235; called by muse, mutect2, varscan2
- ARHGAP15 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99710319; called by muse, mutect2, varscan2
- ARHGAP19 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100363140; called by muse, mutect2, varscan2
- ARHGAP21 | c.5186C>T p.S1729L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs776145004, COSV57601850; called by muse, mutect2, varscan2
- ARHGAP21 | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100256140; called by muse, mutect2, varscan2
- ARHGAP29 | c.1921T>G p.C641G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99558055; called by muse, mutect2, varscan2
- ARHGAP30 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.055); catalogued as COSV100920243; called by muse, mutect2, varscan2
- ARHGAP31 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776509429, COSV51789538, COSV51794964; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP31 | c.2992G>A p.G998R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99957039; called by muse, mutect2, varscan2
- ARHGAP45 | c.2783G>A p.G928E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs778506484, COSV99297530; called by muse, mutect2, varscan2
- ARHGEF10 | c.2219-1G>A p.X740_splice (on ENST00000398564; = p.X715_splice on NM_014629.4) | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100034445; called by muse, mutect2
- ARHGEF10L | c.3566C>T p.S1189F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99392755; called by muse, mutect2, varscan2
- ARHGEF5 | c.3586G>A p.A1196T | Missense Mutation (SNP) | VAF 35/359 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50217208; called by muse, mutect2, varscan2
- ARHGEF6 | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51694974, COSV99166630; called by muse, mutect2, varscan2
- ARIH2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV100711295; called by muse, mutect2, varscan2
- ARMC4 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99518543; called by muse, mutect2, varscan2
- ARMH4 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs764515259, COSV99958116; called by muse, mutect2, varscan2
- ARPP21 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.827); catalogued as COSV51795798; called by muse, mutect2, varscan2
- ARSJ | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as rs777614872, COSV100192652; called by muse, mutect2, varscan2
- ASAP1 | c.1910G>A p.G637E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727207; called by muse, mutect2, varscan2
- ASNS | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as rs1343428756, COSV51550543; called by muse, mutect2, varscan2
- ASPA | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV99559211; called by muse, mutect2, varscan2
- ASS1 | c.771C>T p.V257= | Splice Region (SNP) | VAF 26/66 reads (39%) | catalogued as rs547904731, COSV100752614; called by muse, mutect2, varscan2
- ASXL3 | c.3028C>G p.P1010A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52473696, COSV99324754; called by muse, mutect2, varscan2
- ASXL3 | c.3464C>T p.S1155L | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs377619533, COSV99324595, COSV99324757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATAD3B | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs148312059; called by muse, mutect2, varscan2
- ATG13 | c.1103C>T p.T368I (on ENST00000359513 / NM_001346321.1; = p.T331I on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs760639516, COSV100365714; called by muse, mutect2, varscan2
- ATP11A | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99368279; called by muse, mutect2, varscan2
- ATP13A4 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100710307; called by muse, mutect2, varscan2
- ATP1B2 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs937145780, COSV100006883; called by muse, mutect2, varscan2
- ATP2A1 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs182084601, COSV100706983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A3 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99989103; called by muse, mutect2, varscan2
- ATP2B2 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV100659961; called by muse, mutect2, varscan2
- ATP8B2 | c.1610G>A p.R537K (on ENST00000672630; = p.R504K on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV100527931; called by muse, mutect2, varscan2
- ATRN | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99497066; called by muse, mutect2, varscan2
- ATXN2L | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs755975680, COSV100294254; called by muse, mutect2, varscan2
- ATXN7L2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs961396530, COSV60205965; called by muse, mutect2, varscan2
- AWAT2 | c.849C>T p.V283= | Splice Region (SNP) | VAF 18/22 reads (82%) | catalogued as rs1420568366, COSV52143375; called by muse, mutect2, varscan2
- AXDND1 | c.1376G>A p.W459* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as COSV100858357; called by muse, mutect2, varscan2
- AXL | c.2659G>A p.A887T (on ENST00000301178 / NM_021913.5; = p.A878T on NM_001699.6) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV56571055; called by muse, mutect2, varscan2
- B3GAT1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.021); catalogued as COSV100437873; called by muse, mutect2, varscan2
- B3GAT1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100437876; called by muse, mutect2, varscan2
- B3GNT2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as COSV100114152; called by muse, mutect2, varscan2
- B4GALNT2 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100302547; called by muse, mutect2, varscan2
- B4GALNT2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs202077332, COSV100302580, COSV55925010; called by muse, mutect2, varscan2
- B4GALNT2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs763008576, COSV100302549; called by muse, mutect2, varscan2
- B4GALT5 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100866995; called by muse, varscan2
- B4GALT5 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs769549483, COSV100866996; called by muse, varscan2
- BANK1 | c.1879A>G p.T627A | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100536284; called by muse, mutect2, varscan2
- BATF2 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs867057001, COSV100101764; called by muse, mutect2, varscan2
- BAZ2A | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1391231950, COSV99465928; called by muse, mutect2, varscan2
- BCAR3 | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99550691; called by muse, mutect2, varscan2
- BCCIP | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV52939229, COSV99501621; called by muse, mutect2, varscan2
- BCL9L | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.17); catalogued as COSV99419174; called by muse, mutect2, varscan2
- BCS1L | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99828967; called by muse, mutect2, varscan2
- BEST3 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV100437740; called by muse, mutect2, varscan2
- BICC1 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs773272305, COSV99570485; called by muse, mutect2, varscan2
- BICRA | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV101194302; called by muse, mutect2, varscan2
- BIRC6 | c.12983C>T p.A4328V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428241; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100863739; called by muse, varscan2
- BMP5 | c.450T>G p.F150L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV100895953; called by muse, mutect2, varscan2
- BMP6 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV51674118; called by muse, mutect2, varscan2
- BMPR2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.068); catalogued as COSV101001459; called by muse, mutect2, varscan2
- BPIFB1 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99487354; called by muse, mutect2, varscan2
- BPIFB6 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100848512; called by muse, mutect2, varscan2
- BPTF | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as COSV100074837; called by muse, mutect2, varscan2
- BPTF | c.8852C>T p.P2951L | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100074842; called by muse, mutect2, varscan2
- BRAF | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs863224722, COSV99960167; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAT1 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61395105; called by muse, varscan2
- BRF2 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99604894; called by muse, mutect2, varscan2
- BSN | c.9337C>T p.R3113C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs377523782; called by muse, mutect2, varscan2
- BSND | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1253526087, COSV100987625; called by muse, mutect2, varscan2
- BST1 | c.611G>A p.G204D | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99399902; called by muse, mutect2, varscan2
- BST1 | c.611+1G>A p.X204_splice | Splice Site (SNP) | VAF 39/100 reads (39%) | catalogued as COSV99399905; called by muse, mutect2, varscan2
- BTBD11 | c.3016C>T p.Q1006* (on ENST00000280758 / NM_001018072.2; = p.Q543* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99775568; called by muse, mutect2, varscan2
- BTLA | c.381C>G p.H127Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100569697; called by muse, mutect2, varscan2
- C10orf71 | c.1208A>C p.Q403P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV100110110; called by muse, mutect2, varscan2
- C12orf40 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100210032, COSV61137154; called by muse, mutect2, varscan2
- C12orf50 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV100072214; called by muse, mutect2, varscan2
- C14orf39 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs756018136, COSV100407558; called by muse, mutect2, varscan2
- C14orf93 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100136686; called by muse, mutect2, varscan2
- C16orf54 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1471007854, COSV61476992; called by muse, mutect2, varscan2
- C16orf71 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.923); catalogued as rs527716465, COSV99556298; called by muse, mutect2, varscan2
- C16orf91 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100113681; called by muse, mutect2, varscan2
- C19orf57 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.163); catalogued as COSV60967874; called by muse, mutect2, varscan2
- C3 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV55578080; called by muse, mutect2, varscan2
- C3orf20 | c.2567G>A p.G856E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as COSV53783064; called by muse, mutect2, varscan2
- C4orf19 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1161132103, COSV52648939; called by muse, mutect2, varscan2
- C6orf58 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV100314863; called by muse, mutect2, varscan2
- C6orf89 | c.314G>A p.R105K (on ENST00000373685; = p.R112K on NM_152734.4) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747168988, COSV100769724; called by muse, mutect2, varscan2
- C8orf34 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV61397643; called by muse, mutect2, varscan2
- C9orf131 | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.912); catalogued as rs997628306, COSV100398085; called by muse, mutect2, varscan2
- C9orf50 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV100992323; called by muse, mutect2, varscan2
- CACNA1A | c.4442G>A p.G1481D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100802283; called by muse, mutect2, varscan2
- CACNA1C | c.2337C>T p.A779= | Splice Region (SNP) | VAF 23/53 reads (43%) | catalogued as rs1291124140, COSV100218353; called by muse, mutect2, varscan2
- CACNA1E | c.6885G>A p.M2295I (on ENST00000367573 / NM_001205293.3; = p.M2252I on NM_000721.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100702328; called by muse, mutect2, varscan2
- CACNA1I | c.5446G>A p.G1816R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100360106; called by muse, mutect2, varscan2
- CACNA1S | c.4779G>A p.M1593I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100754960; called by muse, mutect2, varscan2
- CACNA2D3 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99873157; called by muse, mutect2, varscan2
- CACNB2 | c.1327G>A p.E443K (on ENST00000324631 / NM_201596.3; = p.E388K on NM_000724.4) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99994315; called by muse, mutect2, varscan2
- CACNG5 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV99400560; called by muse, mutect2, varscan2
- CADPS2 | c.1653C>T p.G551= | Splice Region (SNP) | VAF 6/54 reads (11%) | catalogued as rs1407212706, COSV100462569; called by muse, mutect2, varscan2
- CALCR | c.344A>T p.K115I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100810509; called by muse, mutect2, varscan2
- CALHM1 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV99588548; called by muse, mutect2, varscan2
- CAMK2B | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99323005; called by muse, mutect2
- CAMP | c.464G>A p.R155K (on ENST00000296435; = p.R152K on NM_004345.5) | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56481942, COSV99601226; called by muse, mutect2, varscan2
- CAND1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV101598273; called by muse, mutect2, varscan2
- CAND2 | c.2173C>T p.Q725* (on ENST00000456430 / NM_001162499.2; = p.Q632* on NM_012298.3) | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99929037; called by muse, varscan2
- CAND2 | c.2297G>A p.G766E (on ENST00000456430 / NM_001162499.2; = p.G673E on NM_012298.3) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.97); PolyPhen benign (0.065); catalogued as COSV99929038; called by muse, mutect2, varscan2
- CAPN11 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs190216536, COSV101291882; called by muse, mutect2, varscan2
- CAPN9 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99680332; called by muse, mutect2, varscan2
- CASKIN2 | c.2902G>A p.G968S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100050386; called by muse, mutect2, varscan2
- CASP14 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs1261476183, COSV99693010; called by muse, mutect2, varscan2
- CASZ1 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100681284; called by muse, mutect2, varscan2
- CAT | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99573218, COSV99573294; called by muse, mutect2
- CATSPERD | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.209); catalogued as rs1408382585, COSV101062539; called by muse, mutect2, varscan2
- CCDC136 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as rs1319576199, COSV99922552; called by muse, mutect2, varscan2
- CCDC157 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs753871516, COSV100199740; called by muse, mutect2, varscan2
- CCDC171 | c.3296G>A p.R1099K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV99900562; called by muse, mutect2, varscan2
- CCDC183 | c.683G>A p.R228K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771264053, COSV100273280; called by muse, mutect2, varscan2
- CCDC30 | c.484G>A p.D162N (on ENST00000340612; = p.D119N on NM_001080850.3) | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100501291, COSV59605274; called by muse, mutect2, varscan2
- CCDC38 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs542768194, COSV60185800; called by muse, mutect2, varscan2
- CCDC57 | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs753978634, COSV100492501; called by muse, mutect2, varscan2
- CCDC59 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs772148437, COSV99810658; called by muse, mutect2, varscan2
- CCDC60 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV100555028; called by muse, mutect2, varscan2
- CCKBR | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100582918; called by muse, mutect2, varscan2
- CD101 | c.1032A>T p.R344S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99869508; called by muse, mutect2, varscan2
- CD109 | c.2648C>T p.S883L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV99753479; called by muse, mutect2, varscan2
- CD163 | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775823; called by muse, mutect2, varscan2
- CD163L1 | c.3816T>A p.D1272E | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550036; called by muse, mutect2, varscan2
- CD163L1 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.184); catalogued as COSV100550037; called by muse, mutect2, varscan2
- CD163L1 | c.1402T>C p.C468R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550038; called by muse, mutect2, varscan2
- CD1A | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 25/136 reads (18%) | catalogued as COSV99192335; called by muse, mutect2, varscan2
- CD1E | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs867813346, COSV63770393; called by muse, mutect2, varscan2
- CD34 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100178345, COSV100178354; called by muse, mutect2, varscan2
- CD40LG | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.953); catalogued as COSV101033487; called by muse, mutect2, varscan2
- CD93 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as rs747600845, COSV99849190; called by muse, mutect2, varscan2
- CDC42BPA | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.107); catalogued as rs772380478, COSV62009001; called by muse, mutect2, varscan2
- CDCA7 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100143496; called by muse, varscan2
- CDH12 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101203218, COSV66392701; called by muse, mutect2, varscan2
- CDH17 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217371; called by muse, mutect2, varscan2
- CDH23 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs543416458, COSV99820676; called by muse, mutect2, varscan2
- CDH26 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs184110890, COSV99722330; called by muse, mutect2, varscan2
- CDH4 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.23); catalogued as COSV100848755; called by muse, mutect2, varscan2
- CDH4 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV100848756; called by muse, mutect2, varscan2
- CDH9 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99144186; called by muse, mutect2, varscan2
- CDHR1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.959); catalogued as COSV100258834, COSV100258855; called by muse, mutect2, varscan2
- CDK12 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs750167967, COSV101420436; called by muse, mutect2, varscan2
- CDKL4 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101115271; called by muse, mutect2, varscan2
- CEACAM16 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.629); catalogued as COSV101312680; called by muse, mutect2, varscan2
- CEACAM5 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55755163; called by muse, mutect2, varscan2
- CEBPZ | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99135528; called by muse, mutect2, varscan2
- CECR2 | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99377794; called by muse, mutect2, varscan2
- CELA2B | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354601773, COSV101025775; called by muse, mutect2, varscan2
- CELF5 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV99485925; called by muse, mutect2, varscan2
- CELSR1 | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434430676, COSV53094364; called by muse, mutect2, varscan2
- CEP250 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100698909; called by muse, mutect2, varscan2
- CEP78 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99450374; called by muse, mutect2, varscan2
- CEP85L | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV100874189; called by muse, mutect2, varscan2
- CERS3 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.315); catalogued as COSV52565710, COSV52567447, COSV52569502; called by muse, mutect2, varscan2
- CFAP206 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as COSV99739466; called by muse, mutect2, varscan2
- CFAP299 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100811630, COSV63881038; called by muse, mutect2, varscan2
- CFAP46 | c.7631C>T p.S2544L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as rs1459282639, COSV99584622; called by muse, mutect2, varscan2
- CFAP46 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100886492; called by muse, mutect2, varscan2
- CFAP58 | c.2254C>T p.Q752* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100866109; called by muse, mutect2, varscan2
- CFAP61 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99844615; called by muse, mutect2, varscan2
- CFAP65 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV58561219; called by muse, mutect2, varscan2
- CFAP65 | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV58559375; called by muse, mutect2, varscan2
- CFAP74 | c.4676C>T p.S1559L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs745920243, COSV60586655; called by muse, mutect2, varscan2
- CFAP74 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs771981252, COSV54565011; called by muse, mutect2, varscan2
- CFHR3 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100807553; called by muse, mutect2, varscan2
- CFTR | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.232); catalogued as CM004892, COSV99135818; called by muse, mutect2, varscan2
- CFTR | c.4004T>A p.L1335H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM972964, COSV99135825; called by muse, mutect2, varscan2
- CGB5 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as rs750519674, COSV100032002; called by mutect2, varscan2
- CGRRF1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99370398; called by muse, mutect2, varscan2
- CHD1L | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100787428; called by muse, mutect2, varscan2
- CHD6 | c.5156C>T p.S1719F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV100950516, COSV100950942; called by muse, mutect2
- CHD6 | c.4452T>G p.I1484M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.131); catalogued as COSV100950947; called by muse, mutect2, varscan2
- CHEK2 | c.1348G>A p.A450T (on ENST00000382580 / NM_001005735.2; = p.A407T on NM_007194.4) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as COSV100101567; called by muse, mutect2, varscan2
- CHEK2 | c.805C>T p.L269F (on ENST00000382580 / NM_001005735.2; = p.L226F on NM_007194.4) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60416645; called by muse, mutect2, varscan2
- CHERP | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs201289066, COSV99550223; called by muse, mutect2, varscan2
- CHI3L1 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99703935; called by muse, mutect2, varscan2
- CHI3L2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763418904, COSV100869281; called by muse, mutect2, varscan2
- CHL1 | c.2506G>A p.D836N (on ENST00000397491 / NM_001253387.1; = p.D852N on NM_006614.4) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV99851065; called by muse, mutect2, varscan2
- CHRNA9 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV100038923; called by muse, mutect2, varscan2
- CHRNG | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as COSV99299076; called by muse, mutect2, varscan2
- CHST3 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV100910451; called by muse, mutect2, varscan2
- CHSY3 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV100519008; called by muse, mutect2, varscan2
- CHTOP | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100904672; called by muse, mutect2, varscan2
- CIC | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.968); catalogued as rs138450756; called by muse, mutect2, varscan2
- CKAP4 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100952441; called by muse, mutect2, varscan2
- CLASP2 | c.2594G>A p.S865N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV100223341; called by muse, mutect2, varscan2
- CLCA1 | c.1031T>C p.V344A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as COSV99322304; called by muse, mutect2, varscan2
- CLCN4 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV101073790; called by muse, mutect2, varscan2
- CLCN6 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.196); catalogued as COSV100411873; called by muse, mutect2, varscan2
- CLEC16A | c.1647C>A p.N549K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV101277952; called by muse, mutect2, varscan2
- CLEC16A | c.2975C>T p.S992F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV99901363; called by muse, mutect2, varscan2
- CLEC4C | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100665439; called by muse, mutect2, varscan2
- CLIP2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99791515; called by muse, mutect2, varscan2
- CLK4 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs375302614; called by muse, mutect2, varscan2
- CLSTN1 | c.2038C>T p.P680S (on ENST00000377298 / NM_001009566.3; = p.P670S on NM_014944.4) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV63647687; called by muse, varscan2
- CLSTN2 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV71724582, COSV71724823; called by muse, mutect2
- CMPK2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1391435644, COSV56775274; called by muse, mutect2, varscan2
- CMYA5 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101484032; called by muse, mutect2, varscan2
- CMYA5 | c.5659A>T p.I1887F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.758); catalogued as COSV101484033; called by muse, mutect2, varscan2
- CMYA5 | c.7306C>T p.P2436S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV101484368, COSV71404171; called by muse, mutect2
- CNBD1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV73075917; called by muse, mutect2, varscan2
- CNBD2 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs1201537623, COSV100839084; called by muse, mutect2, varscan2
- CNKSR2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV54259781; called by muse, mutect2, varscan2
- CNN2 | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs777681837, COSV99567714; called by muse, mutect2, varscan2
- CNP | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs374975038; called by muse, mutect2, varscan2
- CNTN3 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99724246; called by muse, mutect2, varscan2
- CNTN4 | c.2620C>T p.H874Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61872581; called by muse, mutect2, varscan2
- CNTN4 | c.3061A>T p.T1021S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100639214; called by muse, mutect2, varscan2
- CNTN4 | c.3062C>T p.T1021I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs267599765, COSV100639215; called by muse, mutect2, varscan2
- COASY | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55899915; called by muse, mutect2, varscan2
- COCH | c.781G>A p.G261R (on ENST00000216361 / NM_001347720.1; = p.G196R on NM_004086.3) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV99363595; called by muse, mutect2, varscan2
- COL11A2 | c.3926G>A p.G1309E (on ENST00000341947 / NM_080680.3; = p.G1202E on NM_080679.2) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1008221204, COSV59496878; called by muse, mutect2, varscan2
- COL11A2 | c.2093C>T p.P698L (on ENST00000341947 / NM_080680.3; = p.P591L on NM_080679.2) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1205003370, COSV100553928; called by muse, mutect2, varscan2
- COL11A2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100553931; called by muse, varscan2
- COL1A2 | c.3211C>T p.P1071S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99799577; called by muse, mutect2, varscan2
- COL22A1 | c.4855C>T p.R1619W | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs755307992, COSV57325647; called by muse, mutect2, varscan2
- COL24A1 | c.3820C>T p.P1274S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.16); catalogued as COSV65304546; called by muse, mutect2, varscan2
- COL24A1 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV100993236; called by muse, mutect2, varscan2
- COL4A1 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011115, COSV65427351; called by muse, mutect2, varscan2
- COL4A3 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101170377, COSV67415409; called by muse, mutect2, varscan2
- COL4A3 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV101170246, COSV67414539; called by muse, mutect2, varscan2
- COL4A3 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs188942711, COSV67413153; called by muse, mutect2, varscan2
- COL4A4 | c.4015C>T p.P1339S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.883); catalogued as COSV61633365; called by muse, mutect2, varscan2
- COL5A3 | c.3086G>A p.S1029N | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99318791; called by muse, mutect2, varscan2
- COL5A3 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99318793; called by muse, mutect2, varscan2
- COL5A3 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99318795; called by muse, mutect2, varscan2
- COL6A1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV100720150; called by muse, varscan2
- COL6A6 | c.2294T>G p.L765R | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100650206, COSV62018587; called by muse, mutect2, varscan2
- COL9A1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.848); catalogued as COSV57884486; called by muse, mutect2, varscan2
- COL9A2 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101028480; called by muse, mutect2, varscan2
- CPN2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV100103068; called by muse, mutect2, varscan2
- CPNE4 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV70193225; called by muse, mutect2, varscan2
- CPNE4 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV101456678; called by muse, mutect2, varscan2
- CPXM1 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1236791871, COSV101013721; called by muse, mutect2, varscan2
- CR1 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV65455623; called by muse, mutect2, varscan2
- CR2 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV100889622; called by muse, mutect2, varscan2
- CRACD | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99949213; called by muse, varscan2
- CRACD | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949216; called by muse, mutect2, varscan2
- CRACR2A | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV52913364; called by mutect2, varscan2
- CREBBP | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as rs1324562194, COSV52136523, COSV99269523; called by muse, mutect2, varscan2
- CREG2 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1558822629, COSV100240688, COSV61316026; called by muse, mutect2, varscan2
- CROT | c.596G>C p.R199P | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100519503, COSV100519628; called by muse, mutect2, varscan2
- CRP | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54814363; called by muse, mutect2, varscan2
- CSF1R | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV99641731; called by muse, mutect2, varscan2
- CSMD1 | c.8144G>A p.G2715E (on ENST00000520002; = p.G2714E on NM_033225.6) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59315114; called by muse, mutect2, varscan2
- CSMD1 | c.6297G>A p.M2099I (on ENST00000520002; = p.M2098I on NM_033225.6) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.929); catalogued as COSV100147177; called by muse, mutect2
- CSMD1 | c.4277G>A p.G1426E (on ENST00000520002; = p.G1425E on NM_033225.6) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147182; called by muse, mutect2, varscan2
- CSMD1 | c.3142G>A p.D1048N (on ENST00000520002; = p.D1047N on NM_033225.6) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59282193; called by muse, mutect2, varscan2
- CSMD1 | c.2854C>T p.P952S (on ENST00000520002; = p.P951S on NM_033225.6) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs763113241, COSV100147186; called by muse, mutect2, varscan2
- CSMD2 | c.5186G>A p.R1729Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV53910930; called by muse, mutect2, varscan2
- CSMD3 | c.9161G>A p.G3054E (on ENST00000297405 / NM_001363185.1; = p.G2885E on NM_052900.3) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs150721502, COSV52123848, COSV99033682; called by muse, mutect2, varscan2
- CSMD3 | c.7792C>T p.R2598* (on ENST00000297405 / NM_001363185.1; = p.R2494* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 41/85 reads (48%) | catalogued as COSV52119954; called by muse, mutect2, varscan2
- CSMD3 | c.6394C>T p.P2132S (on ENST00000297405 / NM_001363185.1; = p.P2028S on NM_052900.3) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99833072; called by muse, mutect2, varscan2
- CSMD3 | c.2666C>T p.P889L (on ENST00000297405 / NM_001363185.1; = p.P785L on NM_052900.3) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.33); PolyPhen probably damaging (1); catalogued as COSV52095724, COSV99833077; called by muse, mutect2, varscan2
- CTNNA3 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV65628145; called by muse, mutect2, varscan2
- CTNNA3 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as rs777817815, COSV101048920; called by muse, mutect2, varscan2
- CTNS | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99251242; called by muse, mutect2, varscan2
- CTPS1 | c.1697C>T p.T566I | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV101009322; called by muse, mutect2, varscan2
- CUBN | c.7405C>T p.P2469S | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100912598; called by muse, mutect2, varscan2
- CUBN | c.6881C>T p.S2294F | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100912600; called by muse, mutect2, varscan2
- CUL3 | c.61T>C p.F21L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100024219; called by muse, mutect2
- CUL9 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99335315; called by muse, mutect2, varscan2
- CUX2 | c.3365T>C p.M1122T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99919535; called by muse, mutect2, varscan2
- CXCR6 | c.846C>A p.C282* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as rs1351328264, COSV99945593; called by muse, mutect2, varscan2
- CXCR6 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs1162118824, COSV99945596; called by muse, mutect2, varscan2
- CYP27A1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99298478, COSV99298483; called by muse, mutect2, varscan2
- CYP27C1 | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100079829; called by muse, mutect2, varscan2
- CYP2E1 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs200228968, COSV53314177; called by muse, mutect2, varscan2
- CYP2F1 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100462680; called by muse, mutect2, varscan2
- CYP2J2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100968000; called by muse, mutect2, varscan2
- CYP4B1 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV54721388, COSV99597083; called by muse, mutect2
- CYP4Z1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778146409, COSV100497648; called by muse, mutect2, varscan2
- CYSLTR2 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99935218; called by muse, mutect2, varscan2
- CYSLTR2 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99935220; called by muse, mutect2, varscan2
- DALRD3 | c.1178C>T p.S393F (on ENST00000341949 / NM_001009996.3; = p.S226F on NM_018114.5) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100482807, COSV100482959; called by muse, mutect2, varscan2
- DAPK1 | c.3088C>T p.Q1030* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100801723; called by muse, mutect2, varscan2
- DBH | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV55041703; called by muse, mutect2, varscan2
- DBN1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1177464532, COSV52792511; called by muse, mutect2, varscan2
- DCAF13 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV99885255; called by muse, mutect2, varscan2
- DCAF4 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV100611010; called by muse, mutect2, varscan2
- DCLK2 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs771287672, COSV56204688; called by muse, mutect2, varscan2
- DCLRE1B | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV56727529; called by muse, mutect2, varscan2
- DCST2 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV99791882; called by muse, mutect2, varscan2
- DCSTAMP | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV52579944; called by muse, mutect2, varscan2
- DCT | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100986186; called by muse, mutect2, varscan2
- DCTN1 | c.1693C>T p.H565Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1169554082, COSV100720935; called by muse, mutect2, varscan2
- DDI1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100159330, COSV56390718; called by muse, mutect2, varscan2
- DDIAS | c.1561T>C p.S521P | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV100231174; called by muse, mutect2, varscan2
- DDX21 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100826512; called by muse, mutect2, varscan2
- DEFB125 | c.60T>A p.G20= | Splice Region (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101217518; called by muse, mutect2, varscan2
- DENND4C | c.4245G>T p.M1415I (on ENST00000434457 / NM_001330640.2; = p.M1366I on NM_017925.7) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV100727403; called by muse, mutect2, varscan2
- DEPDC1 | c.1540C>T p.L514F | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.694); catalogued as COSV100920288; called by muse, mutect2, varscan2
- DEUP1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.214); catalogued as rs201277348; called by muse, mutect2, varscan2
- DGCR8 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.041); catalogued as rs200010909, COSV100707933; called by muse, mutect2, varscan2
- DGKH | c.2372G>A p.R791K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99818738; called by muse, mutect2, varscan2
- DHDDS | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs747732826, COSV52576955, COSV99360427; called by muse, mutect2, varscan2
- DHDH | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs938502581, COSV55481270, COSV99668483; called by muse, mutect2, varscan2
- DHX16 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100905189; called by muse, mutect2
- DHX8 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99292205; called by muse, mutect2, varscan2
- DIAPH2 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100232578; called by muse, mutect2, varscan2
- DIDO1 | c.6200C>T p.S2067L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99825685; called by muse, mutect2, varscan2
- DIO1 | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100498901; called by muse, mutect2, varscan2
- DIP2A | c.622G>T p.A208S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV100595690; called by muse, mutect2, varscan2
- DIP2A | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as rs1185630981, COSV100595692; called by muse, mutect2, varscan2
- DISC1 | c.2063G>A p.G688E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs367543094; ClinVar: not provided; called by muse, varscan2
- DLGAP2 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101421801; called by muse, mutect2, varscan2
- DMGDH | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV99668920; called by muse, mutect2, varscan2
- DNAH10 | c.5003G>A p.G1668D (on ENST00000409039; = p.G1607D on NM_207437.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV101292207; called by muse, mutect2, varscan2
- DNAH11 | c.5507G>A p.R1836Q | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs754715648, COSV100179089, COSV60945076; called by muse, mutect2, varscan2
- DNAH17 | c.12442G>A p.E4148K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99428233; called by muse, mutect2, varscan2
- DNAH5 | c.10658G>A p.R3553Q | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs144393366, COSV99448734; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.1560G>A p.W520* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100544961; called by muse, mutect2, varscan2
- DNAH8 | c.6095G>A p.G2032E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59478418; called by muse, mutect2, varscan2
- DNAH8 | c.12592C>T p.L4198F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV100544975; called by muse, mutect2, varscan2
- DNAH9 | c.7454C>T p.S2485L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1230926368, COSV52336455, COSV99305555; called by muse, mutect2, varscan2
- DNAJB8 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs768380102, COSV100048282; called by muse, mutect2, varscan2
- DNAL1 | c.169A>T p.T57S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100225793; called by muse, mutect2, varscan2
- DNASE1L2 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1381234602, COSV100065683; called by muse, mutect2, varscan2
- DNASE1L2 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.942); catalogued as COSV100065684; called by muse, mutect2, varscan2
- DNHD1 | c.12864G>A p.W4288* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV99600005; called by muse, mutect2, varscan2
- DNM1 | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100359882; called by muse, mutect2, varscan2
- DNMT3B | c.1998G>A p.E666= | Splice Region (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99141250; called by muse, mutect2, varscan2
- DNMT3L | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.619); catalogued as COSV99533274; called by muse, mutect2, varscan2
- DOCK2 | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs780318765, CM155073, COSV99912073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.1585A>G p.T529A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99811564; called by muse, mutect2
- DOCK3 | c.4093C>T p.P1365S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768190190, COSV56522696; called by muse, mutect2, varscan2
- DOCK6 | c.4870G>A p.A1624T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99625477; called by muse, mutect2, varscan2
- DOK2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99374704; called by muse, mutect2, varscan2
- DOP1A | c.1272_1274del p.L425del | In Frame Del (DEL) | VAF 48/98 reads (49%) | catalogued as rs866106193; called by mutect2, pindel, varscan2
- DPF2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99361609; called by muse, mutect2
- DPF2 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV52891512; called by muse, mutect2
- DPH2 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV99356436; called by muse, mutect2, varscan2
- DPP10 | c.2378A>G p.E793G | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100064212, COSV100066254; called by muse, mutect2, varscan2
- DPP6 | c.2176G>A p.G726R (on ENST00000377770 / NM_001364500.2; = p.G664R on NM_001936.5) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.312); catalogued as rs1217165609, COSV100125241; called by muse, mutect2, varscan2
- DPP6 | c.2177G>A p.G726E (on ENST00000377770 / NM_001364500.2; = p.G664E on NM_001936.5) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV59596946; called by muse, mutect2, varscan2
- DPYD | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100928980; called by muse, mutect2, varscan2
- DPYD | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV64596127; called by muse, mutect2, varscan2
- DPYSL4 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.678); catalogued as rs1360416288, COSV100633934; called by muse, mutect2, varscan2
- DQX1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV101098961; called by muse, mutect2
- DROSHA | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.071); catalogued as COSV100757592; called by muse, mutect2, varscan2
- DSCAML1 | c.971G>C p.R324P (on ENST00000321322; = p.R264P on NM_020693.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV100355808; called by muse, mutect2, varscan2
- DSPP | c.463A>T p.N155Y | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV99217260; called by muse, mutect2, varscan2
- DSPP | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV56809456, COSV99217264; called by muse, mutect2, varscan2
- DTX2 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.166); catalogued as COSV100184571, COSV100184732; called by muse, mutect2, varscan2
- DTX2 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV100184572; called by muse, mutect2, varscan2
- DTX2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100184575; called by muse, mutect2, varscan2
- DUOX1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs752019311, COSV58477676; called by muse, mutect2, varscan2
- DUOX2 | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs371970228; ClinVar: uncertain significance; called by muse, varscan2
- DUSP7 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99623477; called by muse, mutect2, varscan2
- DUSP7 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99623482; called by muse, mutect2, varscan2
- DVL1 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs777653519, COSV66680918; called by muse, mutect2, varscan2
- DYNC1I1 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776143490, COSV61459519; called by muse, mutect2, varscan2
- DYNC2H1 | c.5780C>T p.P1927L | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs367585820; called by muse, mutect2, varscan2
- DYNC2H1 | c.9692A>G p.K3231R | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV100518428; called by muse, mutect2, varscan2
- DYNC2H1 | c.11071G>A p.A3691T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV100518429; called by muse, mutect2, varscan2
- ECE2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.094); catalogued as COSV100668583; called by muse, mutect2, varscan2
- ECE2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1168681969, COSV100668585; called by muse, mutect2, varscan2
- ECPAS | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV99398126; called by muse, mutect2, varscan2
- EFCAB1 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100030734; called by muse, mutect2, varscan2
- EGFR | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51772347; called by muse, mutect2, varscan2
- EIF4E1B | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100024665, COSV53779881; called by muse, mutect2, varscan2
- EIF4G1 | c.1102G>A p.E368K (on ENST00000346169 / NM_198241.3; = p.E172K on NM_004953.5) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); catalogued as rs924110845, COSV100071516; called by muse, mutect2, varscan2
- ELMOD2 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as COSV100062876; called by muse, mutect2, varscan2
- ELP1 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV101010403; called by muse, mutect2, varscan2
- EMB | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); catalogued as rs770439940, COSV100296821; called by muse, mutect2, varscan2
- ENPP6 | c.534G>A p.K178= | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as rs1288558303, COSV99698752; called by muse, mutect2
- EP300 | c.357T>A p.N119K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.684); catalogued as COSV99608397; called by muse, mutect2, varscan2
- EPB41L4B | c.2294C>T p.T765I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100775843; called by muse, mutect2, varscan2
- EPHA4 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.364); catalogued as COSV99916403; called by muse, mutect2, varscan2
- EPHA5 | c.2160T>A p.D720E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99898539; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV51624111, COSV99212420; called by muse, mutect2, varscan2
- EPPK1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV101599824; called by muse, mutect2, varscan2
- EPX | c.1227G>A p.W409* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV56596463; called by muse, mutect2, varscan2
- ERCC6L2 | c.1903G>A p.G635R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99998561; called by muse, mutect2, varscan2
- ESCO2 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100533221; called by muse, mutect2, varscan2
- EVPL | c.2533C>T p.R845* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1239898304, COSV100044440; called by muse, mutect2, varscan2
- EXOC6 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV99591866; called by muse, mutect2, varscan2
- EXOC6B | c.1850A>G p.K617R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99723974; called by muse, mutect2, varscan2
- EYA1 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.435); catalogued as rs1216806432, COSV100379301, COSV58173817; called by muse, mutect2, varscan2
- F5 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889083; called by muse, mutect2, varscan2
- FAAH | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99680014; called by muse, mutect2, varscan2
- FAM135B | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV99423418; called by muse, mutect2, varscan2
- FAM169A | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV100998349; called by muse, mutect2, varscan2
- FAM227B | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV100174934; called by muse, mutect2, varscan2
- FAM229B | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs61746601, COSV64087771; called by mutect2, varscan2
- FAM71B | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100262071; called by muse, mutect2, varscan2
- FAM71B | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57229681; called by muse, mutect2, varscan2
- FAM71C | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV60944522; called by muse, mutect2, varscan2
- FAM83C | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100981560; called by muse, mutect2, varscan2
- FAM83F | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs201378321, COSV100328931; called by muse, mutect2, varscan2
- FAM83G | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs764395974, COSV58759646; called by muse, mutect2, varscan2
- FAM83G | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100525077; called by muse, mutect2, varscan2
- FAP | c.679A>T p.N227Y | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99502125; called by muse, mutect2, varscan2
- FASTKD1 | c.1315A>G p.I439V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV101494289, COSV101494291; called by muse, mutect2, varscan2
- FAT1 | c.10714C>T p.Q3572* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV71671827; called by muse, mutect2, varscan2
- FBXL13 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100501537; called by muse, mutect2, varscan2
- FBXL19 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100608880; called by muse, mutect2, varscan2
- FBXO42 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV100981745; called by muse, mutect2, varscan2
- FBXO46 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.076); catalogued as COSV100480155; called by muse, mutect2, varscan2
- FBXO46 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs377664802; called by muse, mutect2, varscan2
- FCGRT | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99571267; called by muse, mutect2, varscan2
- FCHO2 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755056999, COSV100530587; called by muse, mutect2, varscan2
- FCRL1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1273832117, COSV100839773; called by muse, mutect2, varscan2
- FCRL3 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100943169; called by muse, mutect2, varscan2
- FCRL5 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as rs1395226259, COSV100708881; called by muse, mutect2, varscan2
- FGD3 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV100490534; called by muse, mutect2, varscan2
- FGF18 | c.385T>C p.F129L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99208955; called by muse, mutect2, varscan2
- FGFR1 | c.2410G>A p.E804K (on ENST00000447712 / NM_023110.3; = p.E802K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as rs1238519686, COSV100248050; called by muse, mutect2, varscan2
- FGL1 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV67712596; called by muse, mutect2, varscan2
- FIGNL2 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.031); catalogued as rs370766286; called by muse, mutect2, varscan2
- FKBP15 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV53039279; called by muse, mutect2, varscan2
- FKBP9 | c.655C>A p.R219S | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757765676, COSV99639609; called by muse, mutect2, varscan2
- FLG | c.11672C>T p.S3891F | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs775340348, COSV64242546; called by muse, mutect2, varscan2
- FLG2 | c.4567G>A p.G1523S | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as rs769383959, COSV101165826; called by muse, mutect2, varscan2
- FLNB | c.7150C>T p.P2384S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55891955, COSV99912959; called by muse, mutect2, varscan2
- FLT1 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.95); catalogued as COSV56733186; called by muse, mutect2, varscan2
- FMN2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as rs766875636, COSV100144826; called by muse, mutect2, varscan2
- FMNL1 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV100056458; called by muse, mutect2, varscan2
- FOXD4L1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99380491; called by muse, mutect2, varscan2
- FOXF2 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV99453201; called by muse, mutect2
- FOXK1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV61067576; called by muse, mutect2, varscan2
- FOXM1 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs751824568, COSV100700845; called by muse, mutect2, varscan2
- FOXRED2 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV99340850; called by muse, mutect2, varscan2
- FRAS1 | c.5641G>A p.G1881S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99351412; called by muse, mutect2, varscan2
- FREM2 | c.6799G>A p.G2267R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs777349002, COSV99748554; called by muse, mutect2, varscan2
- FRG2B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1402769271, COSV101423517; called by muse, mutect2
- FRMPD4 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV101042779, COSV66214830; called by muse, mutect2, varscan2
- FSCN1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100435139; called by muse, mutect2
- FSIP2 | c.18958G>A p.E6320K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV58086797; called by muse, mutect2, varscan2
- FTL | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as rs551467958, COSV99509073; called by mutect2, varscan2
- FUCA1 | c.522G>A p.K174= | Splice Region (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100992147; called by muse, mutect2, varscan2
- FUT8 | c.524G>A p.G175E (on ENST00000360689 / NM_001371534.1; = p.G12E on NM_004480.4) | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651347; called by muse, mutect2, varscan2
- FYB1 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60951752, COSV60954887; called by muse, mutect2, varscan2
- FYN | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99991668; called by muse, mutect2, varscan2
- G0S2 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.66); catalogued as rs1289498055, COSV100884458; called by muse, mutect2, varscan2
- G3BP1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.386); catalogued as rs1462263352, COSV100663943; called by muse, mutect2, varscan2
- GAA | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs1567828977, COSV100163177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA6 | c.40C>T p.L14= | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as rs1303778983, COSV99194400; called by muse, mutect2, varscan2
- GABRE | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100944267; called by muse, mutect2, varscan2
- GABRR1 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs773891156, COSV101033896; called by muse, mutect2, varscan2
- GALNT8 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV99362770; called by muse, mutect2, varscan2
- GALNTL6 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1367651288, COSV101487750; called by muse, mutect2, varscan2
- GBE1 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV101450144; called by muse, mutect2, varscan2
- GBF1 | c.1792C>T p.L598F (on ENST00000369983 / NM_001377137.1; = p.L597F on NM_004193.3) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as rs746490881, COSV100890466; called by mutect2, varscan2
- GCM2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101069512; called by muse, mutect2
- GDF2 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs782596402; called by muse, mutect2, varscan2
- GGA3 | c.1990C>T p.L664F (on ENST00000537686 / NM_138619.4; = p.L631F on NM_014001.5) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99822062; called by muse, mutect2, varscan2
- GGT5 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.348); catalogued as rs1445772052, COSV99571486; called by muse, mutect2, varscan2
- GIGYF1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs768030048, COSV51943846; called by muse, mutect2, varscan2
- GIMAP2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99785342; called by muse, mutect2, varscan2
- GIMAP4 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs753014940, COSV55435476; called by muse, mutect2, varscan2
- GJA5 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54784421; called by muse, mutect2, varscan2
- GLB1L2 | c.1713G>A p.W571* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100335314; called by muse, mutect2, varscan2
- GLE1 | c.1723C>G p.R575G | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100012530, COSV100012863, COSV59410135; called by muse, mutect2, varscan2
- GLI1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV99954076; called by muse, mutect2, varscan2
- GLI1 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57369205, COSV99954077; called by muse, mutect2, varscan2
- GLP1R | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100952576; called by muse, mutect2, varscan2
- GLRA3 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs771115012, COSV56857256; called by muse, mutect2, varscan2
- GLYAT | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557304; called by muse, mutect2, varscan2
- GMDS | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1272896273, COSV101071676; called by muse, mutect2, varscan2
- GNA11 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV50017284, COSV99313067; called by muse, mutect2, varscan2
- GOLGB1 | c.7066T>A p.Y2356N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV100510746; called by muse, mutect2, varscan2
- GON4L | c.3091C>T p.P1031S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99674158; called by muse, mutect2, varscan2
- GPAT4 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs775875846, COSV101214006; called by muse, mutect2, varscan2
- GPATCH8 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs769712512, COSV100132506, COSV100132629; called by muse, varscan2
- GPC5 | c.1484G>A p.S495N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100993852, COSV100994220; called by muse, mutect2, varscan2
- GPR139 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs748140778, COSV58502244, COSV58505631; called by muse, mutect2, varscan2
- GPR156 | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs754935658, COSV100251336; called by muse, mutect2, varscan2
- GPR158 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as rs139042739; called by muse, mutect2, varscan2
- GPR52 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1170872463, COSV52308291; called by muse, mutect2, varscan2
- GPR78 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV101223963; called by muse, mutect2, varscan2
- GPR89B | c.374G>A p.W125* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV100032473; called by muse, mutect2, varscan2
- GPRC5C | c.725C>T p.A242V (on ENST00000652232; = p.A197V on NM_018653.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV61238652; called by muse, mutect2, varscan2
- GPRC6A | c.177A>T p.Q59H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100114338; called by muse, mutect2, varscan2
- GPX8 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV99696863; called by muse, mutect2, varscan2
- GRAMD1B | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as COSV100454663; called by muse, mutect2, varscan2
- GRAMD2A | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100550851; called by muse, mutect2, varscan2
- GRAMD2A | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV59033487; called by muse, mutect2, varscan2
- GRAMD2A | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs201775681, COSV100550853; called by muse, mutect2
- GRIK5 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53476483; called by muse, mutect2, varscan2
- GRM3 | c.1641G>A p.M547I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs974856347, COSV64475525; called by muse, mutect2
- GRM5 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100551725; called by muse, mutect2, varscan2
- GRM7 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100736334; called by muse, mutect2, varscan2
- GRPR | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV100977658; called by muse, mutect2, varscan2
- GSAP | c.2384C>T p.S795F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as COSV99990155; called by muse, mutect2, varscan2
- GSDME | c.577-1G>A p.X193_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100742320, COSV61652003; called by muse, mutect2, varscan2
- GTF3C1 | c.3151G>A p.G1051S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649360; called by muse, mutect2, varscan2
- GTF3C5 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100565388; called by muse, mutect2, varscan2
- GUCA1C | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99225662, COSV99226028; called by muse, mutect2, varscan2
- GUCY1B1 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100025559; called by muse, mutect2, varscan2
- GUCY1B1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs779977663, COSV100025561, COSV52374982; called by muse, mutect2, varscan2
- HAP1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as rs782589621, COSV100169658; called by muse, mutect2, varscan2
- HBD | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs528751190, COSV53082024; called by muse, mutect2, varscan2
- HCFC1 | c.4262C>T p.P1421L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100128900; called by muse, mutect2, varscan2
- HCFC1 | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100128907; called by muse, mutect2, varscan2
- HCFC2 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1296415917, COSV99983024; called by muse, mutect2, varscan2
- HCRTR2 | c.1109A>T p.K370I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100904336; called by muse, mutect2, varscan2
- HDGF | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100625693; called by muse, mutect2, varscan2
- HEATR1 | c.5426T>A p.L1809H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100857621; called by muse, mutect2, varscan2
- HEATR1 | c.5425C>T p.L1809F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1199421366, COSV100857622; called by muse, mutect2, varscan2
- HEATR1 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV100857197; called by muse, mutect2, varscan2
- HECTD4 | c.8804C>T p.S2935F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.575); catalogued as COSV101107394; called by muse, mutect2, varscan2
- HECW2 | c.3365G>A p.G1122E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647001; called by muse, mutect2, varscan2
- HECW2 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as rs750600264, COSV99647003; called by muse, mutect2, varscan2
- HELQ | c.2968del p.V990Ffs*7 | Frame Shift Del (DEL) | VAF 33/124 reads (27%) | catalogued as COSV55028844; called by mutect2, pindel, varscan2
- HELQ | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99787641; called by muse, mutect2, varscan2
- HEPH | c.97C>T p.R33W (on ENST00000343002; = p.R87W on NM_138737.5) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs201897918, COSV57970988; called by muse, mutect2, varscan2
- HERC5 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99987656; called by muse, mutect2, varscan2
- HHIP | c.1372A>C p.K458Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as COSV99667174; called by muse, mutect2, varscan2
- HHLA2 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs374073757; called by muse, mutect2, varscan2
- HIC1 | c.1469G>A p.G490E (on ENST00000322941 / NM_001098202.1; = p.G471E on NM_006497.4) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV99558130; called by muse, mutect2, varscan2
- HIF3A | c.1630G>A p.G544R (on ENST00000377670 / NM_152795.4; = p.G475R on NM_022462.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99355617, COSV99355726; called by muse, mutect2, varscan2
- HIPK3 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751432115, COSV57562009; called by muse, mutect2, varscan2
- HIVEP1 | c.7882G>A p.D2628N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as COSV101045106; called by muse, mutect2, varscan2
- HK1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100066452; called by muse, mutect2, varscan2
- HLA-DOA | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV57713822; called by muse, mutect2, varscan2
- HMOX2 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV99566528; called by muse, mutect2, varscan2
- HMX2 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100378753; called by muse, mutect2, varscan2
- HNRNPD | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100002899; called by muse, mutect2, varscan2
- HNRNPK | c.29T>C p.F10S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100366226; called by muse, mutect2, varscan2
- HOXA3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100415447; called by muse, mutect2, varscan2
- HOXA3 | c.480A>T p.K160N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100415448; called by muse, mutect2, varscan2
- HOXD1 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs776337326, COSV100514165; called by muse, mutect2, varscan2
- HPS3 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as rs1559917098, COSV56055340, COSV99937390; called by muse, mutect2, varscan2
- HRNR | c.8462G>A p.G2821E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs781127949, COSV100913425; called by muse, mutect2, varscan2
- HS3ST3A1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1169032210, COSV99404237; called by muse, mutect2
- HSPA12B | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as rs867494918, COSV99653944; called by muse, mutect2, varscan2
- HSPB8 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV99931243; called by muse, mutect2, varscan2
- HSPG2 | c.11246C>T p.P3749L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753071766, COSV101013446; called by muse, mutect2
- HSPG2 | c.7433C>T p.P2478L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377464593; called by muse, mutect2, varscan2
- HSPG2 | c.7432C>T p.P2478S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV65969214; called by muse, mutect2, varscan2
- HSPH1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100184895; called by muse, mutect2, varscan2
- HSPH1 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183798894, COSV100184896; called by muse, mutect2, varscan2
- HTR1D | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024851; called by muse, mutect2, varscan2
- HTR3B | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1565555702, COSV52742930; called by muse, mutect2
- HYAL3 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99807633; called by muse, mutect2, varscan2
- HYDIN | c.8290G>A p.G2764R | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751014034, COSV99992761; called by muse, mutect2, varscan2
- HYDIN | c.6550C>T p.P2184S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1327974538, COSV99992763; called by muse, mutect2, varscan2
- IFT172 | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as rs780136801, COSV99562426; called by muse, mutect2, varscan2
- IFT43 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV53138238; called by muse, mutect2, varscan2
- IGF2BP1 | c.1395G>A p.K465= | Splice Region (SNP) | VAF 47/143 reads (33%) | catalogued as COSV99288609; called by muse, mutect2, varscan2
- IGF2BP2 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV100649081; called by muse, mutect2, varscan2
- IGFBP4 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV99511192; called by muse, mutect2, varscan2
- IGSF10 | c.5330T>C p.V1777A | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV99179481; called by muse, mutect2, varscan2
- IKZF2 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100563505; called by muse, mutect2, varscan2
- IL16 | c.2692C>T p.Q898* (on ENST00000302987 / NM_172217.5; = p.Q197* on NM_004513.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100267486; called by muse, mutect2, varscan2
- IL20RB | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100291052; called by muse, mutect2
- IL2RB | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV53427458; called by muse, mutect2, varscan2
- IL32 | c.296G>A p.G99D (on ENST00000396890 / NM_001308078.4; = p.G53D on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs762192851, COSV99145493; called by muse, mutect2, varscan2
- ILF3 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51553922, COSV99139647; called by muse, mutect2, varscan2
- ILF3 | c.2081G>A p.G694E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99139648; called by muse, mutect2, varscan2
- INPP1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100487196; called by mutect2, varscan2
- IQCH | c.2098-1G>A p.X700_splice | Splice Site (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100245768; called by muse, mutect2, varscan2
- IQCN | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV101148607; called by muse, mutect2, varscan2
- IQGAP1 | c.3898G>A p.G1300S | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs1342603153, COSV99184963; called by muse, mutect2, varscan2
- IQGAP1 | c.3899G>A p.G1300D | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV99184964; called by muse, mutect2, varscan2
- IQSEC2 | c.3077C>T p.P1026L (on ENST00000642864 / NM_001111125.3; = p.P821L on NM_015075.2) | Missense Mutation (SNP) | VAF 64/89 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV100944876; called by muse, mutect2, varscan2
- IRAG1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1282735373, COSV70211831; called by muse, mutect2, varscan2
- ITGA2B | c.2933G>T p.G978V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99288823; called by muse, mutect2, varscan2
- ITGAM | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1376977002, COSV99792322; called by muse, mutect2, varscan2
- ITGBL1 | c.579A>G p.I193M | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs1219873415, COSV101095335; called by muse, mutect2, varscan2
- ITIH1 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.978); catalogued as rs267599896, COSV99835170, COSV99835197; called by muse, mutect2, varscan2
- ITIH1 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243327285, COSV99835198; called by muse, mutect2, varscan2
- ITIH1 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757658201, COSV99835199; called by muse, mutect2, varscan2
- ITIH1 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.933); catalogued as rs770234102, COSV56256770, COSV99835202; called by muse, mutect2, varscan2
- ITIH4 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs376241378; called by muse, mutect2, varscan2
- ITIH5 | c.1730G>A p.W577* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as rs377705957; called by mutect2, varscan2
- ITIH5 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV99904542; called by muse, mutect2, varscan2
- JAKMIP2 | c.2413-1G>A p.X805_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as COSV54598045; called by muse, mutect2, varscan2
- JAKMIP2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs889349639, COSV99508180; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.73); catalogued as rs754288493, COSV100311276; called by muse, mutect2, varscan2
- JMY | c.1326G>T p.K442N | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.998); catalogued as COSV101268005; called by muse, mutect2, varscan2
- JUP | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 32/83 reads (39%) | catalogued as rs992627687, COSV100159537; called by muse, mutect2, varscan2
- KALRN | c.5419C>T p.P1807S (on ENST00000360013 / NM_001024660.4; = p.P110S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as COSV99361870; called by muse, mutect2, varscan2
- KALRN | c.5420C>T p.P1807L (on ENST00000360013 / NM_001024660.4; = p.P110L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV99361875; called by muse, mutect2, varscan2
- KAT6A | c.1356G>T p.W452C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1198342477, COSV99704989; called by muse, mutect2, varscan2
- KATNIP | c.2738G>T p.R913L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750088345, COSV55181907, COSV99850963; called by muse, mutect2, varscan2
- KBTBD12 | c.1003A>T p.I335F | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.134); catalogued as COSV100675414; called by muse, mutect2, varscan2
- KCNH5 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.142); catalogued as rs763289197, COSV59760952; called by muse, mutect2, varscan2
- KCNH7 | c.2597G>A p.R866K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV59807171, COSV59811974; called by muse, mutect2, varscan2
- KCNH8 | c.3047C>T p.S1016L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1371905994, COSV100109619; called by muse, varscan2
- KCNH8 | c.3113C>T p.S1038L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs754806004, COSV60456690; called by muse, varscan2
- KCNJ13 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs761770948, COSV52085931; called by muse, mutect2, varscan2
- KCNJ5 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100610652; called by muse, mutect2, varscan2
- KCNK4 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV100107739; called by muse, mutect2, varscan2
- KCNK7 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100442156; called by muse, mutect2, varscan2
- KCNQ1 | c.1604C>G p.P535R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99326740; called by muse, mutect2, varscan2
- KCNS3 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750734353, COSV100411184; called by muse, mutect2, varscan2
- KCTD10 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV99949224; called by muse, mutect2, varscan2
- KCTD8 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1193448012, COSV63591702, COSV63593631; called by muse, mutect2, varscan2
- KDM3A | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV57219038; called by muse, mutect2, varscan2
- KDM3A | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100460358; called by muse, mutect2, varscan2
- KDM4B | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99346309; called by muse, mutect2, varscan2
- KDM4B | c.2933C>T p.S978F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs267605545, COSV50213135; called by muse, mutect2, varscan2
- KDM6B | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs529894126, COSV99641293; called by muse, varscan2
- KDM7A | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV99134381; called by muse, mutect2, varscan2
- KHDC3L | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100951099; called by muse, mutect2, varscan2
- KHDC4 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as COSV100850792; called by muse, mutect2, varscan2
- KHNYN | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV99249658; called by muse, mutect2, varscan2
- KHSRP | c.345A>G p.G115= | Splice Region (SNP) | VAF 35/66 reads (53%) | catalogued as COSV100383009; called by muse, mutect2, varscan2
- KIAA0100 | c.4591G>A p.G1531R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV101197293; called by muse, mutect2, varscan2
- KIAA1549 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as rs766914391, COSV54329122; called by muse, mutect2, varscan2
- KIAA1614 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV62551235; called by muse, mutect2, varscan2
- KIAA1755 | c.2581G>A p.G861R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777259424, COSV99641955; called by muse, mutect2, varscan2
- KIF13A | c.3749T>G p.I1250S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99435736; called by muse, mutect2, varscan2
- KIF1A | c.4663C>T p.P1555S (on ENST00000320389 / NM_001379639.1; = p.P1547S on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.086); catalogued as COSV100240772; called by muse, mutect2, varscan2
- KIF1A | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV100240775; called by muse, mutect2, varscan2
- KIF21A | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100735430; called by muse, mutect2, varscan2
- KIT | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99854131; called by muse, mutect2, varscan2
- KLHL30 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs867670327, COSV100014272; called by muse, mutect2, varscan2
- KLHL5 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV99785258; called by muse, mutect2, varscan2
- KMT2C | c.9310C>T p.L3104F | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100071350; called by muse, mutect2, varscan2
- KMT2C | c.5441C>T p.P1814L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV100071352; called by muse, mutect2, varscan2
- KMT2D | c.11779C>T p.Q3927* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV56407998; called by muse, mutect2, varscan2
- KRBA1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55443343; called by muse, mutect2, varscan2
- KRT10 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs777365322, COSV99510043; called by muse, mutect2, varscan2
- KRT12 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as rs1266988580, COSV52429656; called by muse, mutect2, varscan2
- KRT14 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as COSV99391001; called by muse, mutect2, varscan2
- KRT14 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1277684376, COSV51422942; called by muse, mutect2, varscan2
- KRT36 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV100057498; called by muse, mutect2, varscan2
- KRT4 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757780016, COSV53407294; called by muse, mutect2, varscan2
- KRT5 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52864170; called by muse, mutect2, varscan2
- KRT5 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV99357991; called by muse, mutect2, varscan2
- KRTAP19-5 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.931); catalogued as COSV100478466, COSV61859758; called by muse, mutect2, varscan2
- KRTAP21-2 | c.181T>G p.C61G | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV100441179; called by muse, mutect2, varscan2
- KRTAP23-1 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as rs766781619, COSV61935701; called by muse, mutect2, varscan2
- LAD1 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs773391681, COSV100943838; called by muse, mutect2, varscan2
- LAMA3 | c.4198C>T p.P1400S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100556697; called by muse, mutect2, varscan2
- LAMB2 | c.3252G>A p.W1084* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100026119; called by muse, varscan2
- LAP3 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99884273; called by muse, mutect2, varscan2
- LCE1D | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 14/114 reads (12%) | PolyPhen benign (0.044); catalogued as COSV58271859; called by muse, mutect2
- LCK | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100287666; called by muse, mutect2, varscan2
- LCTL | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1295061898, COSV58423211; called by muse, mutect2, varscan2
- LDAH | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | catalogued as rs776930106, COSV52968347; called by muse, mutect2, varscan2
- LDB3 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99555124; called by muse, mutect2, varscan2
- LENEP | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV52699948, COSV99422710; called by muse, mutect2, varscan2
- LEPR | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV100756565; called by muse, mutect2, varscan2
- LGI3 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs531970563, COSV60443111, COSV60443347; called by muse, mutect2, varscan2
- LILRB2 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100079294; called by muse, mutect2, varscan2
- LILRB2 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV58746148; called by muse, mutect2, varscan2
- LILRB4 | c.1289C>T p.P430L (on ENST00000391733 / NM_001278428.3; = p.P429L on NM_001278426.3) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as COSV54403393; called by muse, mutect2, varscan2
- LIPC | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs6079; called by muse, mutect2, varscan2
- LIPN | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as COSV101356223; called by muse, mutect2, varscan2
- LLGL2 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99389573; called by muse, mutect2, varscan2
- LMBRD2 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV99682803; called by muse, mutect2, varscan2
- LMBRD2 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99682804; called by muse, mutect2, varscan2
- LMO7 | c.3139G>A p.D1047N (on ENST00000357063; = p.D728N on NM_005358.5) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.127); catalogued as COSV100413030; called by muse, mutect2, varscan2
1,709 further variants in this file (844 protein-altering or splice-affecting, 807 silent, 58 other) are not listed here.
